Somatic mutation profile of tumor specimen TCGA-WE-A8K6-06A (aliquot TCGA-WE-A8K6-06A-11D-A372-08) from TCGA case TCGA-WE-A8K6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.1 years (29,262 days).
Specimen TCGA-WE-A8K6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85dfaceb-1493-46cd-a0aa-8435d42bbdd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8K6-10A (Blood Derived Normal), aliquot TCGA-WE-A8K6-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/467d617c-ff88-4804-9726-bcbe5cd27475

The open-access MAF lists 315 somatic variants for this specimen: 198 protein-altering or splice-affecting, 106 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 106, Nonsense Mutation 13, RNA 7, Intron 4, Splice Site 3, Splice Region 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MYH7 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913633, CM930502, COSV62522280; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC6A1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794726859, CM154016, COSV55116463; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 46/86 reads (53%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV61788292; called by muse, mutect2, varscan2
- ABCD2 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs1427064095, COSV100429690; called by muse, mutect2, varscan2
- ACP2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99922280; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99720351; called by muse, mutect2, varscan2
- ADARB2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs867672739, COSV67219714; called by muse, mutect2, varscan2
- ADCY8 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV53903311; called by muse, mutect2, varscan2
- AKR1C3 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV101003144; called by muse, mutect2, varscan2
- ANK1 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV55885737; called by muse, mutect2, varscan2
- ANK3 | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as rs1299364308, COSV55044663; called by muse, mutect2, varscan2
- AP4B1 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV99871014; called by muse, mutect2, varscan2
- ATP13A2 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV58702777; called by muse, mutect2, varscan2
- ATP13A2 | c.2776T>G p.S926A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100454313; called by muse, mutect2, varscan2
- ATP13A5 | c.2380C>T p.H794Y | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV100665501; called by muse, mutect2, varscan2
- CCDC110 | c.1546A>G p.N516D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100294097; called by muse, mutect2, varscan2
- CCDC17 | c.1174T>A p.Y392N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100601933; called by muse, mutect2, varscan2
- CCDC186 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 74/94 reads (79%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.748); catalogued as COSV100991045, COSV65159298; called by muse, mutect2, varscan2
- CCDC66 | c.1102G>A p.D368N (on ENST00000394672 / NM_001353147.1; = p.D334N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100414207; called by muse, mutect2, varscan2
- CCDC73 | c.1685A>G p.H562R | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100068068; called by muse, mutect2, varscan2
- CCN6 | c.992G>A p.W331* | Nonsense Mutation (SNP) | VAF 36/49 reads (73%) | catalogued as COSV100037137, COSV57890984; called by muse, mutect2, varscan2
- CCR3 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764940028, COSV100656677; called by muse, mutect2, varscan2
- CD163L1 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.194); catalogued as rs1429135668, COSV100550478; called by muse, mutect2, varscan2
- CDH11 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99219353; called by muse, mutect2, varscan2
- CDH17 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99217781; called by muse, mutect2, varscan2
- CDS1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs759347542, COSV99880628; called by muse, mutect2, varscan2
- CEP85L | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV100821336; called by muse, mutect2, varscan2
- CFTR | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs867392195, COSV50067544; called by muse, mutect2, varscan2
- CHD7 | c.6923C>T p.S2308L | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768152792, COSV71111625; called by muse, mutect2, varscan2
- CILK1 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV100607909; called by muse, mutect2, varscan2
- CIPC | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1398003730, COSV100694487, COSV62376901; called by muse, mutect2, varscan2
- CKAP2 | c.536A>G p.Y179C (on ENST00000378037 / NM_001098525.2; = p.Y178C on NM_018204.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99318411; called by muse, mutect2, varscan2
- CLEC1A | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as rs1204027439, COSV100191625; called by muse, mutect2, varscan2
- COL11A1 | c.4021C>T p.P1341S | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100617735; called by muse, mutect2, varscan2
- COL1A1 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751890158, COSV56807243; called by muse, mutect2, varscan2
- COL5A3 | c.2783T>C p.V928A | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99319438; called by muse, mutect2, varscan2
- CORIN | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV99904144; called by muse, mutect2, varscan2
- CTC1 | c.2596C>T p.Q866* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as rs1303118257, COSV100236650; called by muse, mutect2, varscan2
- CUX2 | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99920344; called by muse, mutect2, varscan2
- DCTN4 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238354002, COSV101437573; called by muse, mutect2, varscan2
- DDR1 | c.1590dup p.T531Hfs*21 | Frame Shift Ins (INS) | VAF 72/187 reads (39%) | catalogued as rs771816717; called by mutect2, varscan2
- DLEC1 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100343082; called by muse, mutect2, varscan2
- DLG1 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100015776; called by muse, mutect2, varscan2
- DNAH1 | c.750T>A p.N250K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV101326631; called by muse, mutect2, varscan2
- DNM1L | c.1337G>A p.C446Y | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99846324; called by muse, mutect2, varscan2
- DYNC2H1 | c.1040T>A p.F347Y | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV100519297; called by muse, mutect2, varscan2
- ECM1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60875349; called by muse, mutect2, varscan2
- EYA4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV62046987, COSV62056033; called by muse, mutect2, varscan2
- FAM169A | c.1654T>C p.S552P | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99713772; called by muse, mutect2, varscan2
- FAP | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99502395; called by muse, mutect2, varscan2
- FAT4 | c.11964G>A p.M3988I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.758); catalogued as rs868376679, COSV100629517; called by muse, mutect2, varscan2
- FBXO46 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.66); catalogued as rs771925539, COSV100480336; called by muse, mutect2, varscan2
- FCN3 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs376437282; called by muse, mutect2, varscan2
- FRY | c.1392G>A p.Q464= | Splice Region (SNP) | VAF 44/95 reads (46%) | catalogued as COSV100969704; called by muse, mutect2, varscan2
- GABRG1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs568096519, COSV54949731; called by muse, mutect2, varscan2
- GADD45A | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100921472; called by muse, mutect2, varscan2
- GCNT4 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100466544; called by muse, mutect2, varscan2
- GFPT2 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53809710; called by muse, mutect2, varscan2
- GPRIN2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV65400630; called by muse, mutect2, varscan2
- GRM3 | c.2147G>A p.R716K | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs947762506, COSV64481469; called by muse, mutect2, varscan2
- GRXCR2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1264319289, COSV65061327; called by muse, mutect2, varscan2
- GSTM5 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1482687783, COSV99859790; called by muse, mutect2, varscan2
- HCN2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV99242158; called by muse, mutect2, varscan2
- HIVEP1 | c.3529A>T p.I1177L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV101045486; called by muse, mutect2, varscan2
- HOOK3 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.973); catalogued as COSV100295805; called by muse, mutect2, varscan2
- HTR1E | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100541208, COSV59508442; called by muse, mutect2, varscan2
- IGHV3-30 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs775263481; called by muse, mutect2, varscan2
- INO80D | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.121); catalogued as COSV101305869; called by muse, mutect2, varscan2
- KCNE1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs774614463, COSV100492473; called by muse, varscan2
- KCNQ3 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101196292; called by muse, mutect2, varscan2
- KCNT2 | c.1877G>A p.R626K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99655631, COSV99656886; called by muse, mutect2, varscan2
- KIF1B | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99823861; called by muse, mutect2, varscan2
- KMT2D | c.6812C>T p.P2271L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs587778465, COSV99984517; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT36 | c.462C>T p.I154= | Splice Region (SNP) | VAF 45/68 reads (66%) | catalogued as COSV100057679; called by muse, mutect2, varscan2
- KRT8 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99510230; called by muse, mutect2, varscan2
- LAMB2 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026395; called by muse, mutect2, varscan2
- LAMB2 | c.2875G>A p.G959S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59739435; called by muse, mutect2, varscan2
- LARP6 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780518378, COSV54579870; called by muse, mutect2, varscan2
- LCE1F | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.658); catalogued as COSV57669275; called by muse, varscan2
- LPAR1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 80/89 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100730974; called by muse, mutect2, varscan2
- LRIG3 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 106/191 reads (55%) | catalogued as COSV100292760; called by muse, mutect2, varscan2
- LRRC10 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100825513; called by muse, mutect2, varscan2
- MEF2B | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV99364950; called by muse, mutect2, varscan2
- MFNG | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99325225; called by muse, mutect2, varscan2
- MGLL | c.887C>T p.T296M (on ENST00000398104 / NM_001003794.2; = p.T306M on NM_007283.6) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.059); catalogued as rs747740336, COSV99411818; called by muse, mutect2, varscan2
- MITF | c.830G>A p.S277N (on ENST00000448226 / NM_006722.3; = p.S171N on NM_000248.4) | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV100097245; called by muse, mutect2, varscan2
- MKRN3 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs373739121; called by muse, mutect2, varscan2
- MMUT | c.842T>A p.L281* | Nonsense Mutation (SNP) | VAF 45/103 reads (44%) | catalogued as CM060384, COSV99222489; called by muse, mutect2, varscan2
- MTTP | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99645449; called by muse, mutect2, varscan2
- MUC15 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1186696050, COSV99846577; called by muse, mutect2, varscan2
- MUC16 | c.13150G>A p.G4384R | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as COSV101200644; called by muse, mutect2, varscan2
- MYH8 | c.2931+1G>A p.X977_splice | Splice Site (SNP) | VAF 144/253 reads (57%) | catalogued as COSV101238575; called by muse, mutect2, varscan2
- MYO15A | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.047); catalogued as COSV52769582; called by muse, mutect2, varscan2
- MYO1G | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348964; called by muse, mutect2, varscan2
- MYRIP | c.2522G>A p.R841K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV56881291; called by muse, mutect2, varscan2
- NALCN | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99212704; called by muse, mutect2, varscan2
- NEB | c.3973A>C p.N1325H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99425946; called by muse, mutect2, varscan2
- NF1 | c.4999C>T p.P1667S (on ENST00000358273 / NM_001042492.3; = p.P1646S on NM_000267.3) | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as rs865781825, COSV55986102; called by muse, mutect2, varscan2
- NGFR | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs906612809, COSV99412992; called by muse, mutect2, varscan2
- NLRC4 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as rs201777650, COSV61593361; called by muse, mutect2, varscan2
- NOP56 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100250252, COSV61390466; called by muse, mutect2, varscan2
- NOS2 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100569812; called by muse, mutect2, varscan2
- NOS3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52492127; called by muse, mutect2, varscan2
- NOTCH4 | c.2158G>A p.G720S | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV66678573; called by muse, mutect2, varscan2
- NPAS4 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); catalogued as COSV100215135; called by muse, mutect2, varscan2
- NR1D1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99225707; called by muse, mutect2, varscan2
- OLFM4 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs144683972, COSV99524338; called by muse, mutect2, varscan2
- OR2AG2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100643155, COSV58455183; called by muse, mutect2, varscan2
- OR4C46 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60221146, COSV60221672; called by muse, mutect2, varscan2
- OR4C6 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.314); catalogued as COSV58602970; called by muse, mutect2, varscan2
- OR52B4 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101281598; called by muse, mutect2, varscan2
- OR5B12 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV100222296, COSV56906042; called by muse, mutect2, varscan2
- OR5T3 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV57381226; called by muse, mutect2, varscan2
- OR8I2 | c.309T>G p.F103L | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100135931; called by muse, mutect2, varscan2
- P3H2 | c.1189-1G>A p.X397_splice | Splice Site (SNP) | VAF 61/156 reads (39%) | catalogued as COSV100078138; called by muse, mutect2, varscan2
- PACSIN3 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs765310580, COSV100096505; called by muse, mutect2, varscan2
- PCDHAC2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99145707; called by muse, mutect2, varscan2
- PCDHGB1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53894678; called by muse, mutect2, varscan2
- PCDHGC4 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as rs753979217, COSV99341489; called by muse, mutect2, varscan2
- PCLO | c.4097C>T p.S1366F | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100435548; called by muse, mutect2, varscan2
- PEAK3 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1368058319, COSV100457391; called by muse, mutect2
- PIWIL1 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99806730; called by muse, mutect2, varscan2
- PLA2G2F | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs1232837999, COSV100907922; called by muse, mutect2, varscan2
- PLEKHG4 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357853188, COSV100431124; called by muse, mutect2, varscan2
- PRB3 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.632); catalogued as COSV54389235; called by muse, varscan2
- PROK1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as COSV99602629; called by muse, mutect2, varscan2
- PRORP | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV99156143; called by muse, mutect2, varscan2
- PSG7 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV101343300; called by muse, mutect2, varscan2
- PSORS1C1 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs138995174; called by muse, mutect2, varscan2
- PTPA | c.779C>T p.S260L (on ENST00000337738 / NM_178001.2; = p.S225L on NM_021131.5) | Missense Mutation (SNP) | VAF 114/140 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV61234704; called by muse, mutect2, varscan2
- PTPRN2 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs903720481, COSV101235041; called by muse, mutect2, varscan2
- RANBP3L | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV56958621; called by muse, mutect2, varscan2
- RBM15 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100873479; called by muse, mutect2, varscan2
- RGMA | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.181); catalogued as COSV100224556; called by muse, mutect2, varscan2
- RHO | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs1291957024, COSV56214732, COSV99960727; called by muse, mutect2, varscan2
- RYR1 | c.8278G>A p.E2760K | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV100616533; called by muse, mutect2, varscan2
- RYR2 | c.14809G>A p.E4937K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100772084; called by muse, mutect2, varscan2
- SETDB2 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1423715367, COSV99320912; called by muse, mutect2, varscan2
- SIGLEC9 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs755154431, COSV99142942; called by muse, mutect2, varscan2
- SLC15A1 | c.811-1G>A p.X271_splice | Splice Site (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100919518; called by muse, mutect2, varscan2
- SLC17A8 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 29/122 reads (24%) | catalogued as rs770229890, COSV60121846; called by muse, mutect2, varscan2
- SLC27A6 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs141840840; called by muse, mutect2, varscan2
- SLF1 | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99476161; called by muse, mutect2, varscan2
- SMARCC2 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as rs1373379578, COSV99519580; called by muse, mutect2, varscan2
- SORL1 | c.5195G>A p.G1732E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as CM164126, COSV52751472; called by muse, mutect2, varscan2
- SORL1 | c.6610G>A p.G2204R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99494889; called by muse, mutect2, varscan2
- SPHKAP | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 104/192 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs368367152, COSV60881066; called by muse, mutect2, varscan2
- SPICE1 | c.2297T>A p.V766D | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99871596; called by muse, mutect2, varscan2
- SPICE1 | c.2296G>T p.V766F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.238); catalogued as COSV99871602; called by muse, mutect2, varscan2
- SPTBN5 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs752559834, COSV100311934; called by muse, varscan2
- ST7 | c.1438G>A p.G480R (on ENST00000265437 / NM_021908.3; = p.G457R on NM_018412.4) | Missense Mutation (SNP) | VAF 130/314 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99622614; called by muse, mutect2, varscan2
- STAB2 | c.6601C>T p.H2201Y | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141605819; called by muse, mutect2, varscan2
- SUMF1 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99794993; called by muse, mutect2, varscan2
- SUSD3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100968907; called by muse, mutect2, varscan2
- TDRD9 | c.2353G>A p.G785R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100175453; called by muse, mutect2
- TECPR1 | c.3078C>A p.Y1026* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV101130639; called by muse, mutect2, varscan2
- TECRL | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868813288, COSV67086762; called by muse, mutect2, varscan2
- THSD7A | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1213861708, COSV70264819, COSV70264976; called by muse, mutect2, varscan2
- TMC5 | c.2068G>A p.E690K (on ENST00000396229 / NM_001105248.1; = p.E444K on NM_024780.5) | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs201778492, COSV54900449; called by muse, mutect2, varscan2
- TMCC3 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as COSV99705613; called by muse, mutect2, varscan2
- TMEM132D | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV70598852, COSV70611994; called by muse, mutect2, varscan2
- TMEM241 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776264423, COSV101271775; called by muse, mutect2, varscan2
- TNFSF4 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV99919462; called by muse, mutect2, varscan2
- TNRC6A | c.3607C>T p.P1203S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV100170347; called by muse, mutect2, varscan2
- TNS4 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs775475541, COSV54185245, COSV99564023; called by muse, mutect2, varscan2
- TRIM55 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52551628; called by muse, mutect2, varscan2
- TRIOBP | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); catalogued as rs545506961, COSV100731027; called by muse, varscan2
- TTN | c.84439G>A p.G28147R (on ENST00000591111; = p.G20723R on NM_003319.4) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | PolyPhen possibly damaging (0.509); catalogued as rs761199633, COSV100623179; called by muse, mutect2, varscan2
- TTN | c.50555G>A p.R16852K (on ENST00000591111; = p.R9428K on NM_003319.4) | Missense Mutation (SNP) | VAF 42/156 reads (27%) | PolyPhen benign (0.085); catalogued as COSV60176008; called by muse, mutect2, varscan2
- TTN | c.43664C>T p.P14555L (on ENST00000591111; = p.P7131L on NM_003319.4) | Missense Mutation (SNP) | VAF 54/101 reads (53%) | PolyPhen benign (0.003); catalogued as rs1485291993, COSV100623183; called by muse, mutect2, varscan2
- USH2A | c.9814C>T p.P3272S | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198810318, COSV100239515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP34 | c.9791A>G p.N3264S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as COSV100816068; called by muse, mutect2, varscan2
- USP5 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99978934; called by muse, mutect2, varscan2
- VPS13D | c.10552C>T p.R3518* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as rs752094174, COSV50636269; called by muse, varscan2
- VSIG2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.864); catalogued as COSV99423399; called by muse, mutect2, varscan2
- VWA5A | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1197747080, COSV100827929; called by muse, mutect2, varscan2
- WNK2 | c.5111C>T p.S1704F (on ENST00000297954 / NM_001282394.1; = p.S1667F on NM_006648.3) | Missense Mutation (SNP) | VAF 89/107 reads (83%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as rs569229585, COSV99943859; called by muse, mutect2, varscan2
- XIRP2 | c.5342C>T p.S1781F (on ENST00000628543; = p.S1956F on NM_152381.6) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54688032; called by muse, mutect2, varscan2
- ZC3H4 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 29/54 reads (54%) | catalogued as COSV99452640; called by muse, mutect2, varscan2
- ZDBF2 | c.5800G>A p.A1934T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.195); catalogued as rs1235552730, COSV100985235; called by muse, mutect2, varscan2
- ZFHX4 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51479885, COSV99265906; called by muse, mutect2, varscan2
- ZFPL1 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99297954; called by muse, mutect2, varscan2
- ZHX2 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 101/154 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100073639; called by muse, mutect2, varscan2
- ZNF175 | c.1556A>T p.N519I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as COSV99219680; called by muse, mutect2, varscan2
- ZNF263 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV99527079; called by muse, mutect2, varscan2
- ZNF479 | c.264T>A p.V88= | Splice Region (SNP) | VAF 64/165 reads (39%) | catalogued as COSV100482937; called by muse, mutect2, varscan2
- ZNF486 | c.1310A>G p.K437R | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs1555718394, COSV100631384; called by muse, mutect2, varscan2
- ZNF536 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 110/180 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62819589, COSV62820183, COSV62820593; called by muse, mutect2, varscan2
- ZNF682 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs763641367, COSV100653320; called by muse, mutect2, varscan2
- ZNF683 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV62875960; called by muse, mutect2, varscan2
- ZNF697 | c.99C>A p.D33E | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV101360261, COSV70284025; called by muse, mutect2
- ZNF700 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.05); catalogued as COSV99583707; called by muse, mutect2, varscan2
- ZW10 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV99562800; called by muse, mutect2, varscan2
- ASAH2 | c.1420A>G p.T474A | Missense Mutation (SNP) | VAF 94/118 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- IGHV3-74 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TRGV9 | c.276T>G p.D92E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.02); called by muse, mutect2
- ADGRD1 | c.1536C>T p.F512= | Silent (SNP) | VAF 53/86 reads (62%) | catalogued as COSV99896480; called by muse, mutect2, varscan2
- AHCYL1 | c.1212C>T p.I404= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs371217627; called by muse, mutect2, varscan2
- AHR | c.1635C>T p.N545= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV99620051; called by muse, mutect2, varscan2
- AHR | c.1636C>T p.L546= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV99620054; called by muse, mutect2, varscan2
- ALX4 | c.699C>T p.F233= | Silent (SNP) | VAF 96/239 reads (40%) | catalogued as COSV100241186; called by muse, mutect2, varscan2
- ANKFN1 | c.1443C>T p.F481= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as COSV100593924; called by muse, mutect2, varscan2
- ANKK1 | c.1095C>T p.P365= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100392972; called by muse, varscan2
- ANKS3 | c.651C>T p.I217= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as rs375188024; called by muse, mutect2, varscan2
- ATP6V1E2 | c.384G>A p.L128= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs1379513551, COSV100120786; called by muse, mutect2, varscan2
- C10orf71 | c.1416A>C p.P472= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100110475; called by muse, mutect2, varscan2
- C16orf82 | c.57C>T p.S19= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- C17orf80 | c.1665T>G p.G555= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99278341; called by muse, mutect2, varscan2
- CARD8 | c.1344C>T p.F448= (on ENST00000651546 / NM_001184900.3; = p.F398= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1443022472, COSV100751180; called by muse, mutect2
- CCDC54 | c.840C>T p.T280= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as rs758495479, COSV99660285; called by muse, mutect2, varscan2
- CFAP52 | c.1269C>T p.I423= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs1172900704, COSV100235439; called by muse, mutect2, varscan2
- CNNM4 | c.909C>T p.I303= | Silent (SNP) | VAF 38/154 reads (25%) | catalogued as COSV100998769; called by muse, mutect2, varscan2
- COQ8A | c.408C>T p.S136= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV64658055; called by muse, mutect2, varscan2
- COX7B2 | c.204C>T p.S68= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs146477410; called by muse, mutect2, varscan2
- CTC1 | c.2595C>A p.S865= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV100236654; called by muse, mutect2, varscan2
- CTDSPL | c.744G>A p.T248= (on ENST00000273179 / NM_001008392.2; = p.T237= on NM_005808.3) | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs766128791, COSV56202805; called by muse, mutect2, varscan2
- DPP10 | c.123G>A p.V41= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100069984; called by muse, mutect2, varscan2
- DPY19L4 | c.2160C>T p.S720= | Silent (SNP) | VAF 184/343 reads (54%) | catalogued as COSV101363422; called by muse, mutect2, varscan2
- DRP2 | c.2016C>T p.T672= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100871997; called by muse, mutect2, varscan2
- DYSF | c.1449G>A p.S483= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs755103680, COSV50267426; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- E2F2 | c.831G>A p.L277= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100674847; called by muse, mutect2, varscan2
- EGFL6 | c.876G>A p.K292= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as COSV100789925, COSV63633429; called by muse, mutect2, varscan2
- EPPK1 | c.231C>T p.A77= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1312155619, COSV101599914; called by muse, mutect2, varscan2
- GIMAP6 | c.492G>A p.R164= | Silent (SNP) | VAF 114/259 reads (44%) | catalogued as COSV100188336, COSV61032471; called by muse, mutect2, varscan2
- GPR179 | c.2940C>T p.V980= (on ENST00000621958; = p.V979= on NM_001004334.4) | Silent (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- GRIK3 | c.1686C>T p.S562= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100902219; called by muse, mutect2, varscan2
- H2AC1 | c.261G>A p.A87= | Silent (SNP) | VAF 75/190 reads (39%) | catalogued as rs1393154649, COSV51236665; called by muse, mutect2, varscan2
- HIPK2 | c.1731C>T p.S577= | Silent (SNP) | VAF 62/168 reads (37%) | catalogued as COSV100702424; called by muse, mutect2, varscan2
- HTR1A | c.1089C>T p.I363= | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as rs752106161, COSV100109213; called by muse, mutect2, varscan2
- HYAL3 | c.69A>T p.L23= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV99807804; called by muse, mutect2, varscan2
- IL1RL2 | c.915G>A p.V305= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99960785; called by muse, mutect2, varscan2
- KCNJ15 | c.675G>A p.G225= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100154330; called by muse, mutect2, varscan2
- KCNT2 | c.975T>C p.P325= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99655634; called by muse, mutect2, varscan2
- KIF1B | c.2883C>T p.D961= (on ENST00000377086 / NM_001365952.1; = p.D915= on NM_015074.3) | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV99823863; called by muse, mutect2, varscan2
- KRT85 | c.429C>T p.F143= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs1565769382, COSV99225630; called by muse, mutect2, varscan2
- LRRTM3 | c.516C>T p.I172= | Silent (SNP) | VAF 52/68 reads (76%) | catalogued as COSV63661836, COSV63666421; called by muse, mutect2, varscan2
- MARS1 | c.1186C>T p.L396= | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as COSV100007552; called by muse, mutect2, varscan2
- MBOAT7 | c.445C>T p.L149= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV99824961; called by muse, mutect2, varscan2
- MRC2 | c.915G>A p.T305= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs143442592; called by muse, mutect2, varscan2
- MUC16 | c.16354C>T p.L5452= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as rs1359741654, COSV101200643; called by muse, mutect2, varscan2
- MYO15A | c.636C>T p.A212= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs767692090, COSV99233832; called by muse, mutect2, varscan2
- MYO1G | c.1884G>A p.L628= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as COSV99348967; called by muse, mutect2, varscan2
- NCAPD2 | c.1083C>T p.T361= | Silent (SNP) | VAF 57/106 reads (54%) | catalogued as COSV100217348; called by muse, mutect2, varscan2
- NOP56 | c.1467G>A p.E489= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as COSV100250251; called by muse, mutect2, varscan2
- NOTUM | c.1306C>T p.L436= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV101293816; called by muse, mutect2, varscan2
- NOTUM | c.1305C>T p.H435= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV101293817; called by muse, mutect2, varscan2
- NPNT | c.1296C>T p.I432= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs1448952345, COSV99975336; called by muse, mutect2, varscan2
- OPN1SW | c.198G>A p.R66= | Silent (SNP) | VAF 61/129 reads (47%) | catalogued as COSV99975830; called by muse, mutect2, varscan2
- OR10J3 | c.138C>T p.I46= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV59953920, COSV59955339; called by muse, mutect2, varscan2
- OR10T2 | c.687C>T p.I229= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100555052; called by muse, mutect2, varscan2
- OR2AG2 | c.279C>A p.S93= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV100643154, COSV58455870; called by muse, mutect2, varscan2
- OR2T8 | c.466C>T p.L156= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100178393; called by muse, mutect2, varscan2
- OR4A5 | c.759C>T p.F253= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV60521402, COSV60521592; called by muse, mutect2, varscan2
- OR5M8 | c.222C>T p.S74= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100510739; called by muse, mutect2, varscan2
- OR8S1 | c.519C>T p.I173= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV59599327; called by muse, mutect2, varscan2
- OTUD7A | c.1179C>T p.I393= (on ENST00000307050 / NM_001382637.1; = p.I386= on NM_130901.3) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100192961, COSV61043513; called by muse, mutect2, varscan2
- PCDHGA1 | c.1686C>T p.I562= | Silent (SNP) | VAF 121/225 reads (54%) | catalogued as COSV100965999; called by muse, mutect2, varscan2
- PDCL3 | c.495G>A p.T165= | Silent (SNP) | VAF 22/188 reads (12%) | catalogued as rs763038336, COSV51809001, COSV51810304; called by muse, mutect2
- PEMT | c.195C>T p.F65= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV55131484; called by muse, mutect2, varscan2
- PIP | c.18C>T p.L6= | Silent (SNP) | VAF 150/379 reads (40%) | catalogued as rs949360001, COSV99344219; called by muse, mutect2, varscan2
- PKP1 | c.1092G>A p.K364= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as COSV99825555; called by muse, mutect2, varscan2
- PNMA8A | c.663G>A p.T221= | Silent (SNP) | VAF 66/104 reads (63%) | catalogued as rs369554909, COSV58137212; called by muse, mutect2, varscan2
- PRAMEF19 | c.789C>T p.F263= | Silent (SNP) | VAF 78/226 reads (35%) | called by muse, mutect2, varscan2
- PROM2 | c.1380C>T p.P460= | Silent (SNP) | VAF 37/58 reads (64%) | catalogued as rs1303361294, COSV100469249; called by muse, mutect2, varscan2
- RAB3C | c.195C>T p.I65= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs140076663; called by muse, mutect2, varscan2
- RELN | c.1332G>A p.T444= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs759118667, COSV100634410; called by muse, mutect2, varscan2
- RNF32 | c.492C>T p.T164= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV100311549, COSV100311567; called by muse, mutect2, varscan2
- SCN10A | c.2631G>A p.G877= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV71861499; called by muse, mutect2, varscan2
- SENP5 | c.1818C>T p.F606= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1172060296, COSV100052187; called by muse, mutect2, varscan2
- SLC13A5 | c.1410C>T p.T470= | Silent (SNP) | VAF 69/114 reads (61%) | catalogued as COSV99546077; called by muse, mutect2, varscan2
- SLC26A8 | c.828G>A p.A276= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs749676353, COSV100839455; called by muse, mutect2, varscan2
- SLC51A | c.441G>A p.T147= | Silent (SNP) | VAF 52/292 reads (18%) | catalogued as rs140082619; called by muse, varscan2
- SLITRK1 | c.1419G>A p.L473= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV101000023; called by muse, mutect2, varscan2
- SMTNL1 | c.1209C>T p.T403= (on ENST00000399154; = p.T440= on NM_001105565.2) | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV101216493; called by muse, mutect2, varscan2
- SNCB | c.177C>T p.T59= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs757603167, COSV100031329; called by muse, mutect2, varscan2
- SPATA31E1 | c.1632C>T p.G544= | Silent (SNP) | VAF 110/127 reads (87%) | catalogued as rs1418110744, COSV100350810; called by muse, mutect2, varscan2
- STC1 | c.282G>A p.E94= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as COSV51688076, COSV51689021; called by muse, mutect2, varscan2
- SUPT6H | c.3501C>T p.I1167= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100112630; called by muse, mutect2, varscan2
- TAS2R39 | c.222G>A p.R74= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as COSV101489413; called by muse, mutect2, varscan2
- TBC1D24 | c.79C>T p.L27= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99565181; called by muse, mutect2, varscan2
- TELO2 | c.855G>A p.L285= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1352778923, COSV99248584; called by muse, mutect2, varscan2
- TMEM131L | c.4089C>T p.S1363= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99547881; called by muse, mutect2, varscan2
- TMEM132D | c.1368C>T p.S456= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs367648175; called by muse, mutect2, varscan2
- TOP3B | c.765C>T p.L255= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1307180704, COSV64118406; called by muse, mutect2, varscan2
- TPO | c.129G>A p.L43= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs1351592394, COSV100219571, COSV100221757; called by muse, mutect2, varscan2
- TRAV38-1 | c.258G>A p.V86= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- TRIM55 | c.1646G>A p.*549= | Silent (SNP) | VAF 144/232 reads (62%) | catalogued as rs1167472533, COSV99396175; called by muse, mutect2, varscan2
- TTC1 | c.117G>A p.Q39= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1474521611, COSV99180655; called by muse, mutect2
- TTN | c.43023C>T p.I14341= (on ENST00000591111; = p.I6917= on NM_003319.4) | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV59885707; called by muse, mutect2, varscan2
- TTN | c.18783G>A p.V6261= (on ENST00000591111; = p.V5334= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100601210, COSV100623184; called by muse, mutect2, varscan2
- TUBAL3 | c.1119G>A p.G373= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100990576; called by muse, mutect2, varscan2
- TXNL1 | c.168C>T p.F56= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV54178252; called by muse, mutect2, varscan2
- UBA5 | c.831T>C p.G277= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV99393332; called by muse, mutect2, varscan2
- UNC45B | c.327G>A p.R109= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV52093147; called by muse, mutect2, varscan2
- UNC45B | c.1371C>T p.F457= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99269014; called by muse, mutect2, varscan2
- USHBP1 | c.216G>A p.K72= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99394441; called by muse, mutect2, varscan2
- VPS13D | c.10551C>T p.F3517= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV99167811; called by muse, varscan2
- ZCCHC10 | c.22C>T p.L8= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100147996; called by muse, mutect2, varscan2
- ZNF282 | c.1869C>T p.I623= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs1202550544, COSV100021814; called by muse, mutect2, varscan2
- ZNF479 | c.1050G>A p.E350= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100482935; called by muse, mutect2, varscan2
- ZNF91 | c.12C>T p.T4= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV56080580; called by muse, mutect2, varscan2
- ZP2 | c.1389G>A p.V463= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as COSV99559697; called by muse, mutect2, varscan2
- C2orf83 | n.156G>A | RNA (SNP) | VAF 21/60 reads (35%) | catalogued as rs765813142, COSV100018183; called by muse, mutect2, varscan2
- C6orf223 | n.651C>T | RNA (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100350506; called by muse, mutect2, varscan2
- C9orf106 | n.104C>G | RNA (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- HERC2P3 | n.612G>A | RNA (SNP) | VAF 13/62 reads (21%) | called by mutect2, varscan2
- MAZ | c.1280-467C>T | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as rs1200481587, COSV99361352; called by muse, mutect2, varscan2
- MAZ | c.1280-466C>T | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as rs369815478, COSV99361014; called by muse, mutect2, varscan2
- NACA | c.71-4271C>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100771504; called by mutect2, varscan2
- PARGP1 | n.617C>T | RNA (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- SERPINA13P | n.653C>T | RNA (SNP) | VAF 40/75 reads (53%) | catalogued as rs756650450; called by muse, mutect2, varscan2
- TTN | c.10360+3502G>A | Intron (SNP) | VAF 23/99 reads (23%) | catalogued as rs544185501, COSV60104878; called by muse, mutect2, varscan2
- XIST | n.8847C>T | RNA (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
